Gene-level copy-number profile of tumor specimen ALCH-B43B-TTP1-A from ALCHEMIST case ALCH-B43B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.7 years (30,560 days).
Specimen ALCH-B43B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a8a0d755-3bf2-4f4b-b1e6-84522794a863.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B43B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/33428a4c-d6f3-49c2-8101-5f4de42b6f1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 3,530; copy number 2: 54,871; copy number 3: 380; copy number 4: 15; copy number 5: 3; copy number 7: 5; copy number 8: 2; copy number 9: 10; copy number 12: 3; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr1:38,043,829–38,046,793, 1 gene: POU3F1.
- chr1:43,968,351–43,991,170, 4 genes: AL357079.2, DPH2, ATP6V0B, B4GALT2.
- chr2:130,139,287–130,182,750, 2 genes (within-gene range 0–2): CCDC74B, SMPD4.
- chr7:102,186,819–102,264,979, 3 genes (within-gene range 0–2): AC005086.4, AC005086.3, AC005088.1.
- chr8:27,459,756–27,479,883, 1 gene: CHRNA2.
- chr8:41,645,177–41,650,817, 1 gene: NKX6-3.
- chr8:41,660,441–41,665,566, 3 genes (within-gene range 0–2): MIR486-1, MIR486-2, AC113133.1.
- chr10:102,106,489–102,120,368, 1 gene: LDB1.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr12:109,713,825–109,770,495, 1 gene (within-gene range 0–2): FAM222A.
- chr12:113,392,445–113,426,301, 1 gene (within-gene range 0–2): SDS.
- chr14:77,821,030–77,821,142, 1 gene (within-gene range 0–2): Y_RNA.
- chr14:104,724,229–104,747,325, 1 gene: ADSS1.
- chr15:25,187,536–25,203,308, 9 genes (within-gene range 0–2): SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18.
- chr15:25,243,614–25,250,940, 5 genes (within-gene range 0–2): SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:67,163,385–67,198,918, 6 genes (within-gene range 0–1): AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4.
- chr17:50,464,496–50,468,906, 1 gene (within-gene range 0–2): CHAD.
- chr21:43,053,191–43,107,570, 2 genes: CBS, U2AF1.
- chr21:43,169,008–43,172,805, 1 gene: CRYAA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,598,012–1,600,135, 1 gene, copy number 8: FNDC10.
- chr9:64,878,790–64,889,063, 2 genes, copy number 5: AC125634.1, RNU6-1293P.
- chr16:33,043,609–33,545,812, 14 genes, copy number 7–9: AC145350.2, AC145350.3, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC136944.1, AC136944.2.
- chr17:51,312,609–51,335,165, 1 gene, copy number 5 (within-gene range 2–5): LINC02071.
- chr21:43,414,483–43,479,534, 4 genes, copy number 12–16: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,133,610–44,210,114, 2 genes, copy number 7–8 (within-gene range 2–8): GATD3A, LINC01678.

Autosomal genes at a single copy (total copy number 1): 752. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
